Somatic mutation profile of tumor specimen C3N-02730-01 (aliquot CPT0207870007) from CPTAC case C3N-02730, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 40.1 years (14,629 days).
Specimen C3N-02730-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 374d10a8-16f8-4c80-aa38-e7400bfb014c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02730-71 (Blood Derived Normal), aliquot CPT0207930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc9240a4-a856-4259-84a5-ac383afe17bc

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 3, Splice Site 2, 5'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 117/706 reads (17%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 26/451 reads (6%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2
- BAZ1B | c.4261C>T p.R1421C | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as rs530271123, COSV100289935, COSV100290163; called by muse, mutect2
- CYP2D7 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs747255571; called by muse, mutect2
- G6PC | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM001693; called by muse, mutect2
- HTT | c.8735C>T p.P2912L | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166653969; called by muse, mutect2
- LTBP3 | c.2501C>A p.A834E | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54216487; called by muse, mutect2
- NMUR2 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs555065239, COSV54920656; called by muse, mutect2, varscan2
- POU4F2 | c.546C>A p.H182Q | Missense Mutation (SNP) | VAF 36/445 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.263); catalogued as rs748041541; called by muse, mutect2
- RRP12 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs554015140; called by muse, mutect2
- TPK1 | c.512G>T p.R171M | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV63640783; called by muse, mutect2
- VARS1 | c.2953C>T p.R985C | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1371966979; called by muse, mutect2
- VCL | c.1841C>T p.T614M | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs748140302; called by muse, mutect2
- ASCC3 | c.3483C>A p.H1161Q | Missense Mutation (SNP) | VAF 8/221 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.229); called by muse, mutect2
- ATP13A4 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAPZB | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CDC42EP1 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2
- DPYS | c.1444-1G>A p.X482_splice | Splice Site (SNP) | VAF 15/394 reads (4%) | called by muse, mutect2
- FLNA | c.3706G>A p.G1236S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LINS1 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TAF1C | c.1792C>A p.Q598K | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.053); called by muse, mutect2
- HDAC9 | c.2475C>T p.N825= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as rs374625281; called by muse, mutect2
- PDGFRA | c.501G>A p.V167= | Silent (SNP) | VAF 14/233 reads (6%) | catalogued as rs868447819; called by muse, mutect2
- SIRPA | c.1008C>T p.D336= | Silent (SNP) | VAF 26/488 reads (5%) | catalogued as rs745363259, COSV61537336; called by muse, mutect2
- PKHD1 | c.-23G>A | 5'UTR (SNP) | VAF 8/238 reads (3%) | called by muse, mutect2
- SLC22A17 | n.1253A>G | RNA (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
